TARGET case TARGET-40-PAUJZR — Osteosarcoma (TARGET-OS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Osseous and Chondromatous Neoplasms; Primary site: Bones, joints and articular cartilage of limbs. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/50ad7546-21ee-5705-bf9e-ee26ecc3d135

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 8 years; Vital status: Alive.

Diagnoses (1)
1. Osteosarcoma, NOS: ICD-O-3 morphology code: 9180/3; ICD-10 code: C40.0; Tissue or organ of origin: Long bones of upper limb, scapula and associated joints; Classification of tumor: primary; Age at diagnosis: 8.4 years (3,075 days); Year of diagnosis: 2011; Metastasis at diagnosis: No Metastasis; Days to last follow up: 853 days (2.3 years).
   Treatment given: Protocol identifier: AOST06B1.

Follow-up (1 entry)
- Days to follow up: 853 days (2.3 years); Event-free: no event (relapse, second malignancy or death) recorded through day 853; Year of follow up: 2014.

Biospecimens (2 samples)
- Sample TARGET-40-PAUJZR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-40-PAUJZR-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_OS_ClinicalData_Discovery_and_Validation_Percent_Tumor_Supplement_20230329.xlsx (sheet OS Data), for sample TARGET-40-PAUJZR-01A-01:
- Specimen Type: Frozen solid tumor
- Diagnosis Confirmed: yes
- % Tumor Nuclei: Top from Biopsy: 99
- % Non Tumor Nuclei: Top from Biopsy: 1
- % Cellular Tumor: Top from Biopsy: 98
- % Normal: Top from Biopsy: 1
- % Stroma: Top from Biopsy: 0
- % Necrosis: Top from Biopsy: 1
- % Tumor Nuclei: Bottom from Biopsy: 99
- % Non Tumor Nuclei: Bottom from Biopsy: 1
- % Cellular Tumor: Bottom from Biopsy: 98
- % Normal: Bottom from Biopsy: 1
- % Stroma: Bottom from Biopsy: 0
- % Necrosis: Bottom from Biopsy: 1
- PASS/FAIL: PASS

Additional fields from the TARGET clinical supplement workbook TARGET_OS_ClinicalData_Validation_20230329.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 853
- Disease at diagnosis: Non-metastatic (confirmed)
- Primary tumor site: Arm/hand
- Specific tumor site: Humerus
